Somatic mutation profile of tumor specimen TCGA-AX-A06H-01A (aliquot TCGA-AX-A06H-01A-11D-A122-09) from TCGA case TCGA-AX-A06H, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIA; Tumor grade: G1; Age at diagnosis: 61.0 years (22,270 days).
Specimen TCGA-AX-A06H-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 81a3db47-07a3-4cca-98d0-e5681c3a57ba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AX-A06H-10A (Blood Derived Normal), aliquot TCGA-AX-A06H-10A-01D-A122-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e9baea97-3acb-4644-ad1e-2b7c09273d02

The open-access MAF lists 520 somatic variants for this specimen: 391 protein-altering or splice-affecting, 122 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 229, Silent 122, Frame Shift Del 107, Frame Shift Ins 26, Nonsense Mutation 12, In Frame Del 7, Splice Site 7, RNA 3, Splice Region 3, Intron 2, 5'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB4 | c.1015del p.S339Qfs*3 | Frame Shift Del (DEL) | VAF 18/86 reads (21%) | catalogued as rs753104429, CD034702, COSV55939298; ClinVar: pathogenic; called by mutect2, varscan2
- CHD2 | c.522del p.V175* | Frame Shift Del (DEL) | VAF 40/141 reads (28%) | catalogued as rs748694853; ClinVar: likely pathogenic; called by mutect2, varscan2
- FGFR2 | c.1647T>A p.N549K | Missense Mutation (SNP) | VAF 67/244 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913476, COSV60638757, COSV60639738; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GLB1 | c.1577dup p.W527Lfs*5 | Frame Shift Ins (INS) | VAF 23/99 reads (23%) | catalogued as rs794729217; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- NF1 | c.2033dup p.I679Dfs*21 | Frame Shift Ins (INS) | VAF 8/40 reads (20%) | catalogued as rs587781807; ClinVar: pathogenic; called by mutect2, varscan2
- NF1 | c.5780del p.L1927Wfs*15 (on ENST00000358273 / NM_001042492.3; = p.L1906Wfs*15 on NM_000267.3) | Frame Shift Del (DEL) | VAF 38/163 reads (23%) | catalogued as rs1135402880; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- PIK3R1 | c.1745+1del p.X582_splice (on ENST00000521381 / NM_181523.3; = p.X312_splice on NM_181504.4) | Splice Site (DEL) | VAF 48/260 reads (18%) | hotspot (GDC flag); catalogued as COSV57129726; called by mutect2, pindel, varscan2
- PTEN | c.275A>G p.D92G | Missense Mutation (SNP) | VAF 48/184 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1114167623, CM132264, COSV64288500, COSV64301396, COSV64302611; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.448G>T p.E150* | Nonsense Mutation (SNP) | VAF 36/118 reads (31%) | catalogued as rs786204934, CM110145, COSV64289396, COSV64297896; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLC19A3 | c.74dup p.S26Lfs*19 | Frame Shift Ins (INS) | VAF 51/190 reads (27%) | catalogued as rs786205213; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- A2M | c.2183C>T p.T728M | Missense Mutation (SNP) | VAF 42/149 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as rs777702464, COSV59386026; called by muse, mutect2, varscan2
- ACAP3 | c.181G>A p.V61I | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs773200216, COSV61222131; called by muse, mutect2, varscan2
- ACBD3 | c.568del p.R190Gfs*43 | Frame Shift Del (DEL) | VAF 48/156 reads (31%) | catalogued as rs757016425; called by mutect2, varscan2
- ADCY3 | c.3031C>T p.Q1011* | Nonsense Mutation (SNP) | VAF 8/32 reads (25%) | catalogued as COSV53167237; called by muse, mutect2, varscan2
- ADGRG3 | c.1339A>G p.M447V | Missense Mutation (SNP) | VAF 51/172 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs373107897; called by muse, mutect2, varscan2
- ADRA2A | c.532G>A p.V178I | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.053); catalogued as COSV54527824; called by muse, mutect2
- AGAP1 | c.2458G>A p.V820M (on ENST00000304032 / NM_001037131.3; = p.V767M on NM_014914.5) | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as rs767278330, COSV58324926; called by muse, mutect2, varscan2
- AGPAT4 | c.907del p.R303Gfs*7 | Frame Shift Del (DEL) | VAF 8/33 reads (24%) | catalogued as rs750826126, COSV57248889; called by mutect2, pindel, varscan2
- AGRN | c.3833G>A p.R1278H | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs542631667, COSV65069382; called by muse, mutect2, varscan2
- AIMP1 | c.512C>T p.A171V | Missense Mutation (SNP) | VAF 45/131 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV63638322; called by muse, mutect2, varscan2
- AKAP8L | c.1421A>G p.H474R | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as COSV68473383; called by muse, mutect2, varscan2
- AKAP9 | c.6638T>C p.V2213A (on ENST00000359028; = p.V2189A on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/117 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.022); catalogued as COSV62344937; called by muse, mutect2, varscan2
- ALDH1A3 | c.207C>T p.P69= | Splice Region (SNP) | VAF 5/23 reads (22%) | catalogued as rs770866879, COSV60901628; called by muse, mutect2, varscan2
- ANK3 | c.11333A>C p.K3778T | Missense Mutation (SNP) | VAF 6/184 reads (3%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV55056432; called by muse, mutect2
- ANKRD24 | c.3083G>A p.R1028Q | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.746); catalogued as rs747619057, COSV53670145; called by muse, mutect2, varscan2
- ANKRD50 | c.3512C>T p.T1171I | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV72385504; called by muse, mutect2, varscan2
- ANKS1B | c.2063G>A p.G688D | Missense Mutation (SNP) | VAF 15/189 reads (8%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.808); catalogued as COSV100242974, COSV61349472; called by muse, mutect2
- ARHGEF18 | c.409G>A p.D137N (on ENST00000359920 / NM_001130955.2; = p.D33N on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 69/232 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as rs764176584, COSV60469514; called by muse, mutect2, varscan2
- ARID1A | c.1636del p.Q546Rfs*73 | Frame Shift Del (DEL) | VAF 56/239 reads (23%) | catalogued as COSV61383992, COSV61391080; called by mutect2, pindel, varscan2
- ARID1A | c.3977dup p.Q1327Afs*11 | Frame Shift Ins (INS) | VAF 15/75 reads (20%) | catalogued as COSV61376881; called by mutect2, pindel, varscan2
- ARID5B | c.2262del p.H754Qfs*25 | Frame Shift Del (DEL) | VAF 15/80 reads (19%) | catalogued as COSV54419699; called by mutect2, pindel, varscan2
- ARMCX5 | c.695T>A p.L232Q | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV55766505; called by muse, mutect2, varscan2
- ASIC5 | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.044); catalogued as COSV72232693; called by muse, mutect2, varscan2
- ATP12A | c.2353G>A p.D785N | Missense Mutation (SNP) | VAF 20/181 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54515670; called by muse, mutect2, varscan2
- ATRX | c.7295C>T p.T2432I | Missense Mutation (SNP) | VAF 37/146 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.053); catalogued as COSV64876097; called by muse, mutect2, varscan2
- B2M | c.139G>A p.V47M | Missense Mutation (SNP) | VAF 63/217 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV62563956; called by muse, mutect2, varscan2
- BAG6 | c.2027C>T p.A676V (on ENST00000676571; = p.A629V on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1290462845, COSV52990296; called by muse, mutect2, varscan2
- BBS7 | c.790G>A p.G264R | Missense Mutation (SNP) | VAF 14/304 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs932897330, COSV52656350; called by muse, mutect2
- BCOR | c.4340G>A p.R1447H (on ENST00000378444 / NM_001123385.2; = p.R1413H on NM_017745.6) | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60706405; called by muse, mutect2, varscan2
- BRD3 | c.71del p.P24Rfs*24 | Frame Shift Del (DEL) | VAF 14/24 reads (58%) | catalogued as rs763134487; called by mutect2, varscan2
- BTBD8 | c.13G>T p.G5W | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as rs1296971555, COSV61546188; called by muse, mutect2, varscan2
- BTRC | c.402G>T p.K134N (on ENST00000370187 / NM_033637.4; = p.K98N on NM_003939.5) | Missense Mutation (SNP) | VAF 39/193 reads (20%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.005); catalogued as COSV64561177, COSV64562466; called by muse, mutect2, varscan2
- CCDC18 | c.774del p.V259Wfs*15 | Frame Shift Del (DEL) | VAF 26/130 reads (20%) | catalogued as rs746565576, COSV58142470; called by mutect2, varscan2
- CCDC191 | c.2339A>G p.Q780R | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.651); catalogued as COSV55671955; called by muse, mutect2, varscan2
- CCNL2 | c.1390C>T p.R464W | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs751164412, COSV68766331; called by muse, mutect2, varscan2
- CCT8L2 | c.1654dup p.I552Nfs*6 | Frame Shift Ins (INS) | VAF 58/192 reads (30%) | catalogued as rs780034402; called by mutect2, varscan2
- CD19 | c.1529C>T p.A510V (on ENST00000324662 / NM_001178098.2; = p.A509V on NM_001770.6) | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); catalogued as COSV61187956; called by muse, mutect2, varscan2
- CDCP1 | c.2339G>A p.C780Y | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56105318; called by muse, mutect2, varscan2
- CECR2 | c.2882C>T p.P961L (on ENST00000342247 / NM_001290047.2; = p.P778L on NM_001290046.1) | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); catalogued as rs754756829, COSV52840539; called by muse, mutect2, varscan2
- CELSR2 | c.5131G>T p.G1711W | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV54771100; called by muse, mutect2
- CHRND | c.314dup p.D106Gfs*15 | Frame Shift Ins (INS) | VAF 17/92 reads (18%) | catalogued as rs1223256610; called by mutect2, pindel, varscan2
- CLPTM1L | c.837del p.F279Lfs*2 | Frame Shift Del (DEL) | VAF 31/158 reads (20%) | catalogued as rs777479912; called by mutect2, pindel, varscan2
- COL19A1 | c.399A>G p.I133M | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.106); catalogued as COSV59565310, COSV59566837; called by muse, mutect2, varscan2
- COL1A2 | c.3815G>A p.C1272Y | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM1513293, COSV51957546; called by muse, mutect2, varscan2
- COL3A1 | c.928C>T p.R310W | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs757062073, COSV58587203; called by muse, mutect2, varscan2
- COL4A1 | c.4555T>G p.Y1519D | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV65425075; called by muse, mutect2, varscan2
- COL5A1 | c.492G>A p.K164= | Splice Region (SNP) | VAF 32/104 reads (31%) | catalogued as COSV65668569; called by muse, mutect2, varscan2
- COPS4 | c.179T>C p.V60A | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.166); catalogued as COSV52314766; called by muse, varscan2
- CREB3L4 | c.577_579del p.E193del | In Frame Del (DEL) | VAF 24/104 reads (23%) | catalogued as rs769844271; called by pindel, varscan2
- CSF2RA | c.82C>T p.R28* | Nonsense Mutation (SNP) | VAF 48/165 reads (29%) | catalogued as rs756203389, COSV62623463, COSV62624556; called by muse, mutect2, varscan2
- CSPG4 | c.4504G>A p.G1502S | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as rs377495164, COSV57891077; called by muse, mutect2, varscan2
- CSRNP1 | c.229C>A p.R77S | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.103); catalogued as COSV56187987; called by muse, mutect2, varscan2
- CTSV | c.872C>T p.S291L | Missense Mutation (SNP) | VAF 84/279 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.396); catalogued as rs771264161, COSV52344711; called by muse, mutect2, varscan2
- CYTH1 | c.529A>G p.N177D | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV63120186; called by muse, mutect2, varscan2
- DAB2IP | c.3073del p.H1025Tfs*5 (on ENST00000408936; = p.H997Tfs*5 on NM_032552.3) | Frame Shift Del (DEL) | VAF 13/55 reads (24%) | catalogued as rs751187768; called by mutect2, varscan2
- DCLK1 | c.108C>A p.S36R | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV55184923; called by muse, mutect2, varscan2
- DDX27 | c.2072del p.K691Rfs*4 | Frame Shift Del (DEL) | VAF 28/84 reads (33%) | catalogued as rs766714372; called by mutect2, varscan2
- DIS3L2 | c.1618C>T p.R540C | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs573031156, COSV56053668; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAAF5 | c.836G>A p.R279H | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs978606639, COSV52415625; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH17 | c.10954C>T p.R3652C | Missense Mutation (SNP) | VAF 41/179 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs749125075, COSV67753741; called by muse, mutect2, varscan2
- DNAH7 | c.3770del p.N1257Ifs*11 | Frame Shift Del (DEL) | VAF 36/104 reads (35%) | catalogued as rs34468832; called by mutect2, varscan2
- DNAH7 | c.1037del p.K346Sfs*23 | Frame Shift Del (DEL) | VAF 25/97 reads (26%) | catalogued as rs761292636; called by mutect2, varscan2
- DNAJA2 | c.899del p.P300Lfs*4 | Frame Shift Del (DEL) | VAF 21/118 reads (18%) | catalogued as COSV57694509; called by mutect2, pindel, varscan2
- DNMT3B | c.151T>C p.S51P | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.424); catalogued as COSV52418076, COSV99140403; called by muse, mutect2, varscan2
- DPAGT1 | c.698del p.F233Sfs*28 | Frame Shift Del (DEL) | VAF 56/200 reads (28%) | catalogued as rs35482889; called by mutect2, varscan2
- DRD1 | c.767C>T p.P256L | Missense Mutation (SNP) | VAF 38/154 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs182894202; called by muse, mutect2, varscan2
- DSCAML1 | c.1363G>A p.A455T (on ENST00000321322; = p.A395T on NM_020693.4) | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.629); catalogued as rs148882662, COSV58389757; called by muse, mutect2, varscan2
- DYNC1I2 | c.169del p.R57Gfs*13 | Frame Shift Del (DEL) | VAF 33/118 reads (28%) | catalogued as rs772082432; called by mutect2, varscan2
- DYNC2H1 | c.5567del p.L1856* | Frame Shift Del (DEL) | VAF 79/284 reads (28%) | catalogued as COSV62086569; called by mutect2, pindel, varscan2
- DYRK2 | c.1466G>A p.G489D (on ENST00000344096 / NM_006482.3; = p.G416D on NM_003583.4) | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV59846033; called by muse, mutect2, varscan2
- DYSF | c.238T>C p.F80L | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.37); catalogued as COSV50312808; called by muse, mutect2, varscan2
- E2F2 | c.659C>T p.T220M | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs1298811001, COSV62276424; called by muse, mutect2, varscan2
- EDEM3 | c.814G>A p.V272M | Missense Mutation (SNP) | VAF 48/183 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as rs528899420, COSV58924062; called by muse, mutect2, varscan2
- EEF1AKMT1 | c.412G>A p.V138I | Missense Mutation (SNP) | VAF 13/227 reads (6%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.572); catalogued as rs747096067, COSV66964617, COSV66965297; called by muse, mutect2
- ELOA2 | c.1580C>T p.P527L | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs202004416, COSV55298439; called by muse, mutect2, varscan2
- ELOA2 | c.580G>A p.G194R | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs777399852, COSV55298449; called by muse, mutect2, varscan2
- ENKUR | c.389C>G p.T130S | Missense Mutation (SNP) | VAF 24/270 reads (9%) | SIFT tolerated (0.68); PolyPhen benign (0.013); catalogued as rs916966053, COSV58633138; called by muse, mutect2
- ENPEP | c.2736del p.F912Lfs*21 | Frame Shift Del (DEL) | VAF 50/196 reads (26%) | catalogued as rs768719919; called by mutect2, pindel, varscan2
- ENSA | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 48/206 reads (23%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.801); catalogued as COSV55026582; called by muse, mutect2, varscan2
- EPDR1 | c.576del p.F192Lfs*27 | Frame Shift Del (DEL) | VAF 15/75 reads (20%) | catalogued as COSV99554285; called by mutect2, pindel, varscan2
- EPHA1 | c.736del p.R246Afs*14 | Frame Shift Del (DEL) | VAF 6/13 reads (46%) | catalogued as rs776794841; called by mutect2, varscan2
- EPHA10 | c.2604del p.R869Gfs*10 | Frame Shift Del (DEL) | VAF 9/30 reads (30%) | catalogued as rs1449193125; called by mutect2, pindel, varscan2
- EPN2 | c.1408del p.T470Qfs*5 | Frame Shift Del (DEL) | VAF 58/206 reads (28%) | catalogued as rs756461692; called by mutect2, varscan2
- FAHD2B | c.842del p.P281Qfs*26 | Frame Shift Del (DEL) | VAF 31/146 reads (21%) | catalogued as rs751966944; called by mutect2, pindel, varscan2
- FAM13A | c.2146C>T p.R716W | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771377780, COSV52001912; called by muse, mutect2, varscan2
- FAM193A | c.2497del p.M833Wfs*23 | Frame Shift Del (DEL) | VAF 38/164 reads (23%) | catalogued as rs768952789; called by mutect2, pindel, varscan2
- FGR | c.737C>T p.P246L | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs1205492492, COSV64969473; called by muse, mutect2, varscan2
- FHOD3 | c.2933del p.P978Lfs*10 (on ENST00000359247 / NM_001281739.3; = p.P995Lfs*10 on NM_025135.5) | Frame Shift Del (DEL) | VAF 44/164 reads (27%) | catalogued as rs1289548251; called by mutect2, pindel, varscan2
- FLII | c.533C>T p.T178M | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs140059134; called by muse, mutect2, varscan2
- FLNC | c.6442G>A p.A2148T | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.907); catalogued as rs1373731120, COSV57955358; called by muse, mutect2, varscan2
- FLT4 | c.1422-1G>A p.X474_splice | Splice Site (SNP) | VAF 10/36 reads (28%) | catalogued as COSV56107352; called by muse, mutect2, varscan2
- FMN2 | c.2867C>T p.P956L | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.393); catalogued as rs752237802, COSV60416576; called by muse, mutect2, varscan2
- FMNL1 | c.3188G>T p.G1063V | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV58956786; called by muse, mutect2, varscan2
- FNDC3B | c.1999C>G p.L667V | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.269); catalogued as COSV61041616; called by muse, mutect2, varscan2
- FRMD6 | c.688G>A p.A230T (on ENST00000344768 / NM_001267046.2; = p.A222T on NM_152330.4) | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.059); catalogued as rs374236968; called by muse, mutect2, varscan2
- FSIP1 | c.522del p.K174Nfs*5 | Frame Shift Del (DEL) | VAF 25/102 reads (25%) | catalogued as rs755530261; called by mutect2, pindel, varscan2
- FURIN | c.356C>A p.P119H | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.572); catalogued as COSV51576565; called by muse, mutect2, varscan2
- GBP4 | c.1916G>A p.R639H | Missense Mutation (SNP) | VAF 69/249 reads (28%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs374000169; called by muse, mutect2, varscan2
- GEMIN4 | c.1250G>A p.R417H | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs772978681, COSV56745756; called by muse, mutect2, varscan2
- GINM1 | c.954G>T p.E318D | Missense Mutation (SNP) | VAF 54/197 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as COSV100168026, COSV59502265; called by muse, mutect2, varscan2
- GOLGA2 | c.2929del p.Y977Tfs*9 | Frame Shift Del (DEL) | VAF 32/102 reads (31%) | catalogued as rs763679060; called by mutect2, varscan2
- GRM6 | c.1876G>A p.V626I | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.42); PolyPhen benign (0.19); catalogued as rs756767401, COSV51440333; called by muse, mutect2, varscan2
- GUCY2C | c.2890G>A p.V964M | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.378); catalogued as rs1382390012, COSV53789825; called by muse, mutect2, varscan2
- H3C11 | c.371A>G p.D124G | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.939); catalogued as COSV58899924; called by muse, mutect2, varscan2
- HAUS5 | c.719del p.P240Qfs*73 | Frame Shift Del (DEL) | VAF 5/39 reads (13%) | catalogued as rs1169026761; called by mutect2, pindel, varscan2
- HCFC1 | c.3118C>T p.H1040Y | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.014); catalogued as COSV60071958; called by muse, mutect2, varscan2
- HELZ2 | c.6163C>T p.R2055C (on ENST00000467148 / NM_001037335.2; = p.R1486C on NM_033405.3) | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs376190650; called by muse, mutect2
- HERC1 | c.989G>A p.C330Y | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV71247665; called by muse, mutect2, varscan2
- HIPK3 | c.1428+1G>A p.X476_splice | Splice Site (SNP) | VAF 32/109 reads (29%) | catalogued as COSV57562335; called by muse, mutect2, varscan2
- HLX | c.539G>A p.R180H | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1321310977, COSV65044717; called by muse, mutect2
- HMGCLL1 | c.877G>A p.A293T | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as rs774579523, COSV51444342; called by muse, mutect2, varscan2
- HSD3B7 | c.1018C>T p.R340C | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs779021008, COSV52680446; called by muse, mutect2, varscan2
- IGSF1 | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.205); catalogued as COSV63837288; called by muse, mutect2
- IKZF1 | c.952G>A p.A318T | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV58781912, COSV58785360; called by muse, mutect2, varscan2
- IL12RB1 | c.1426G>A p.G476S | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762298729, COSV59097039; called by muse, mutect2, varscan2
- IL27RA | c.1781C>T p.P594L | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs139468413, COSV54598786; called by muse, mutect2, varscan2
- INSR | c.4019C>T p.A1340V | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs200400127; called by muse, mutect2, varscan2
- INTS3 | c.754C>T p.R252W | Missense Mutation (SNP) | VAF 65/250 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV59677366; called by muse, mutect2, varscan2
- IPO11 | c.2419del p.S807Lfs*22 | Frame Shift Del (DEL) | VAF 72/304 reads (24%) | catalogued as rs1561359523; called by mutect2, varscan2
- IQCC | c.419C>T p.T140M | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0.006); catalogued as rs754677770, COSV52208719; called by mutect2, varscan2
- ITGAV | c.2155G>A p.A719T | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.884); catalogued as rs771156414, COSV53709535, COSV53711983; called by muse, mutect2, varscan2
- JAK1 | c.1289del p.P430Rfs*2 | Frame Shift Del (DEL) | VAF 13/68 reads (19%) | catalogued as rs755650243; called by mutect2, pindel, varscan2
- JKAMP | c.166G>A p.A56T (on ENST00000554271 / NM_001284201.1; = p.A42T on NM_016475.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 104/351 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0.009); catalogued as rs1430847306, COSV54199339; called by muse, mutect2, varscan2
- JPH1 | c.823G>A p.A275T | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60610700; called by muse, mutect2, varscan2
- KAT6A | c.824C>T p.A275V | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1220943324, COSV55905737, COSV55910420; called by muse, mutect2, varscan2
- KHDC3L | c.463G>A p.G155R | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.361); catalogued as rs769425065, COSV64863247; called by muse, mutect2, varscan2
- KIAA1549 | c.5051G>A p.R1684H | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54313224; called by muse, mutect2
- KLF15 | c.1118G>A p.R373H | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56180006; called by muse, mutect2
- KLF9 | c.278T>C p.M93T | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV65807605; called by muse, mutect2, varscan2
- KLHL11 | c.567del p.E190Nfs*22 | Frame Shift Del (DEL) | VAF 22/73 reads (30%) | catalogued as rs782080498; called by mutect2, pindel, varscan2
- KLK8 | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT tolerated (0.48); PolyPhen benign (0.014); catalogued as rs371793414; called by muse, mutect2, varscan2
- KMT2B | c.7204_7208del p.K2402Efs*18 | Frame Shift Del (DEL) | VAF 24/76 reads (32%) | catalogued as COSV55820504; called by mutect2, pindel, varscan2
- KMT2C | c.3313C>T p.Q1105* | Nonsense Mutation (SNP) | VAF 18/97 reads (19%) | catalogued as COSV51435850; called by muse, varscan2
- KNG1 | c.1789G>T p.G597C | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as COSV53977566, COSV99405771; called by muse, mutect2, varscan2
- LARP4B | c.1411G>A p.A471T | Missense Mutation (SNP) | VAF 39/142 reads (27%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as COSV60221322; called by muse, mutect2, varscan2
- LDB2 | c.1053del p.W352Gfs*33 | Frame Shift Del (DEL) | VAF 40/154 reads (26%) | catalogued as COSV58768620; called by mutect2, pindel, varscan2
- LRGUK | c.975T>A p.N325K | Missense Mutation (SNP) | VAF 42/129 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.108); catalogued as COSV53637457; called by muse, mutect2, varscan2
- LRIG3 | c.1169G>A p.R390Q | Missense Mutation (SNP) | VAF 44/212 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs201211812, COSV57863345; called by muse, mutect2, varscan2
- LRP1 | c.4675C>T p.R1559W | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.332); catalogued as rs759297890, COSV54510266; called by muse, mutect2, varscan2
- LRP1B | c.3895C>A p.Q1299K | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.057); catalogued as COSV67214728, COSV67218446; called by muse, mutect2, varscan2
- LRP6 | c.4162G>A p.G1388R | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.682); catalogued as COSV53786946; called by muse, mutect2, varscan2
- LRRK1 | c.4441C>T p.R1481C | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52610187; called by muse, mutect2, varscan2
- MAB21L3 | c.325G>T p.G109C | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as rs1466926118, COSV101046423, COSV65673838; called by muse, mutect2, varscan2
- MACF1 | c.20049G>T p.E6683D (on ENST00000372915; = p.E4728D on NM_012090.5) | Missense Mutation (SNP) | VAF 12/77 reads (16%) | catalogued as COSV57119696; called by muse, mutect2, varscan2
- MACO1 | c.306del p.F102Lfs*47 | Frame Shift Del (DEL) | VAF 81/314 reads (26%) | catalogued as rs752439249; called by mutect2, varscan2
- MAGEB3 | c.763C>T p.L255F | Missense Mutation (SNP) | VAF 57/178 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV64397041; called by muse, mutect2, varscan2
- MAGEC3 | c.1313A>G p.D438G | Missense Mutation (SNP) | VAF 9/113 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.035); catalogued as rs763078465, COSV53579695; called by muse, mutect2
- MAP3K6 | c.3754G>A p.A1252T | Missense Mutation (SNP) | VAF 39/209 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.185); catalogued as COSV58871131, COSV58871666; called by muse, mutect2, varscan2
- MAP3K9 | c.2066G>A p.R689H (on ENST00000554752 / NM_001284230.1; = p.R703H on NM_033141.4) | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs147124893; called by muse, mutect2, varscan2
- MAST1 | c.446G>A p.G149D | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV52246271; called by muse, mutect2, varscan2
- MED24 | c.2099T>C p.L700P | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.93); catalogued as COSV62418501; called by muse, mutect2, varscan2
- MED9 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); catalogued as rs1342679748, COSV51957529; called by muse, mutect2, varscan2
- MEX3B | c.1030G>C p.A344P | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.036); catalogued as COSV61663372; called by muse, mutect2, varscan2
- MMP3 | c.415A>G p.K139E | Missense Mutation (SNP) | VAF 46/160 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV55405960; called by muse, mutect2, varscan2
- MNX1 | c.733C>T p.R245C | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM003821, COSV53318141; called by muse, mutect2
- MOGS | c.881del p.P294Lfs*11 | Frame Shift Del (DEL) | VAF 13/49 reads (27%) | catalogued as rs750486813; called by mutect2, pindel, varscan2
- MUC5B | c.3845G>A p.G1282D | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71591931; called by muse, mutect2, varscan2
- MYBPH | c.166A>G p.T56A | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55138016; called by muse, mutect2, varscan2
- MYH14 | c.1779C>G p.D593E | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.155); catalogued as COSV51816759; called by muse, mutect2, varscan2
- MYH14 | c.4799G>A p.R1600H | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs373651452; called by muse, mutect2, varscan2
- MYH7 | c.3592G>A p.D1198N | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730880778, COSV62518898; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO9A | c.4123A>G p.S1375G | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.096); catalogued as COSV61848105; called by muse, mutect2, varscan2
- NDUFS1 | c.1868T>G p.I623R | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs201634181; called by muse, mutect2
- NEIL2 | c.31C>T p.H11Y | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); catalogued as COSV52706744; called by muse, mutect2, varscan2
- NES | c.3583A>G p.T1195A | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV63960949; called by muse, mutect2, varscan2
- NLRP9 | c.1244T>A p.L415H | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60462733; called by muse, mutect2, varscan2
- NMNAT2 | c.832C>T p.Q278* | Nonsense Mutation (SNP) | VAF 6/70 reads (9%) | catalogued as COSV54268183; called by muse, mutect2
- NPHP4 | c.2318A>G p.Q773R | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV65394750; called by muse, mutect2, varscan2
- NR3C1 | c.218C>T p.A73V | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.003); catalogued as rs376527205; called by muse, mutect2, varscan2
- NUDT14 | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as rs776403747, COSV59650356; called by muse, mutect2, varscan2
- NUGGC | c.1135C>T p.R379* | Nonsense Mutation (SNP) | VAF 51/192 reads (27%) | catalogued as rs753815960, COSV58432423; called by muse, mutect2, varscan2
- NXPH1 | c.695C>T p.S232F | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV68314280; called by muse, mutect2, varscan2
- OCEL1 | c.319C>T p.H107Y | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV52243676; called by muse, mutect2
- OR51E1 | c.466del p.A156Lfs*3 | Frame Shift Del (DEL) | VAF 17/78 reads (22%) | catalogued as rs1564877761; called by mutect2, pindel, varscan2
- OR8U1 | c.542A>G p.D181G | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.973); catalogued as rs770668728, COSV56415476; called by muse, mutect2, varscan2
- OR9G4 | c.181T>G p.F61V | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1190620781, COSV57248464; called by muse, mutect2, varscan2
- P2RY8 | c.321G>A p.M107I | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV67177254; called by muse, mutect2, varscan2
- PAPOLB | c.163G>T p.E55* | Nonsense Mutation (SNP) | VAF 27/94 reads (29%) | catalogued as COSV68200615; called by muse, mutect2, varscan2
- PARP9 | c.1981T>C p.F661L | Missense Mutation (SNP) | VAF 104/419 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV64450639; called by muse, mutect2, varscan2
- PAX6 | c.1124del p.P375Hfs*7 | Frame Shift Del (DEL) | VAF 18/72 reads (25%) | catalogued as CM011452; called by mutect2, pindel, varscan2
- PCDHA8 | c.1814C>T p.A605V | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs782672387, COSV65326193, COSV65329961; called by muse, mutect2, varscan2
- PCDHA9 | c.763G>A p.V255I | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.041); catalogued as rs782439109, COSV65326199; called by muse, mutect2, varscan2
- PCDHB8 | c.392C>A p.S131Y | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.684); catalogued as COSV50765566; called by muse, mutect2, varscan2
- PCDHGB4 | c.244G>A p.G82R | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768800761, COSV53941614; called by muse, mutect2, varscan2
- PDCD6IP | c.602del p.L201* | Frame Shift Del (DEL) | VAF 52/210 reads (25%) | catalogued as rs781474699; called by mutect2, varscan2
- PDGFD | c.640del p.I214Lfs*68 | Frame Shift Del (DEL) | VAF 22/80 reads (28%) | catalogued as rs1333395128; called by mutect2, pindel, varscan2
- PDIA5 | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs752562236, COSV60248953; called by muse, mutect2, varscan2
- PFKP | c.793del p.R265Gfs*2 | Frame Shift Del (DEL) | VAF 55/219 reads (25%) | catalogued as rs1161592176; called by mutect2, pindel, varscan2
- PI4KA | c.5057A>C p.Q1686P | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55410323; called by muse, mutect2, varscan2
- PIGZ | c.1117_1119del p.L373del | In Frame Del (DEL) | VAF 14/58 reads (24%) | catalogued as rs778545255; called by pindel, varscan2
- PKD2L2 | c.116del p.L39* | Frame Shift Del (DEL) | VAF 97/390 reads (25%) | catalogued as rs1406261366; called by mutect2, pindel, varscan2
- PLCG2 | c.491G>A p.R164Q | Missense Mutation (SNP) | VAF 44/135 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); catalogued as rs766422892, COSV63869304; called by muse, mutect2, varscan2
- PLK3 | c.254G>A p.G85D | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.411); catalogued as COSV64728820; called by muse, mutect2
- PLOD2 | c.1799C>A p.S600Y | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); catalogued as COSV51464484; called by muse, mutect2, varscan2
- PNLIP | c.533C>T p.A178V | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.282); catalogued as COSV65040317; called by muse, mutect2, varscan2
- POLA1 | c.25+1del p.X9_splice | Splice Site (DEL) | VAF 10/56 reads (18%) | catalogued as COSV66885911; called by mutect2, pindel, varscan2
- PPA1 | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV64683737; called by muse, mutect2, varscan2
- PPEF1 | c.1952A>G p.N651S | Missense Mutation (SNP) | VAF 6/168 reads (4%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV62995656; called by muse, mutect2
- PPFIBP1 | c.2872C>T p.R958W (on ENST00000318304 / NM_177444.3; = p.R952W on NM_003622.4) | Missense Mutation (SNP) | VAF 51/216 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57291035; called by muse, mutect2, varscan2
- PPP1R12B | c.1880A>G p.E627G | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51784412; called by muse, mutect2, varscan2
- PPP6R2 | c.2395G>A p.V799I (on ENST00000216061 / NM_001365836.1; = p.X765_splice on NM_014678.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.009); catalogued as COSV53293096; called by muse, mutect2, varscan2
- PRICKLE3 | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs782611814, COSV66234429, COSV66234502; called by muse, mutect2
- PRICKLE4 | c.107C>T p.P36L (on ENST00000359201; = p.P76L on NM_013397.6) | Missense Mutation (SNP) | VAF 30/156 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs752836843, COSV100138923, COSV59254307; called by muse, mutect2, varscan2
- PRKRIP1 | c.363G>T p.E121D | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.193); catalogued as COSV61349922; called by muse, mutect2, varscan2
- PROSER1 | c.2420C>T p.P807L | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.999); catalogued as rs746249118, COSV61487244; called by muse, mutect2, varscan2
- PTPRCAP | c.464C>T p.T155M | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs138220100; called by muse, mutect2, varscan2
- PTPRM | c.568C>T p.R190W | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.56); catalogued as rs531199027, COSV59857059; called by muse, mutect2, varscan2
- PWWP2A | c.1001del p.K334Rfs*25 | Frame Shift Del (DEL) | VAF 91/396 reads (23%) | catalogued as COSV61048365; called by mutect2, pindel, varscan2
- RASAL2 | c.3265A>G p.I1089V | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62713543; called by muse, mutect2, varscan2
- RBMX | c.1170A>T p.R390S | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV57809223; called by muse, mutect2
- RC3H1 | c.1705C>A p.P569T | Missense Mutation (SNP) | VAF 15/175 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs1557931709, COSV51200238; called by muse, mutect2
- RERE | c.3934C>T p.R1312W | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1205852331, COSV61941550; called by muse, mutect2, varscan2
- RFWD3 | c.917G>A p.R306H | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1404862026, COSV63097763; called by muse, mutect2, varscan2
- RPA1 | c.1400C>G p.T467R | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV54609200; called by muse, mutect2, varscan2
- RPS3 | c.89C>A p.A30D | Missense Mutation (SNP) | VAF 61/232 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.314); catalogued as COSV53704677; called by muse, mutect2, varscan2
- SCRN1 | c.143C>T p.P48L | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as rs774314954, COSV54130387; called by muse, mutect2, varscan2
- SDF2 | c.530A>G p.H177R | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.895); catalogued as rs766623300, COSV55931726; called by muse, mutect2, varscan2
- SEC24B | c.2014-1G>T p.X672_splice | Splice Site (SNP) | VAF 80/308 reads (26%) | catalogued as COSV54498821; called by muse, mutect2, varscan2
- SF3B4 | c.674T>C p.V225A | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.023); catalogued as CX148149, COSV54965304; called by muse, mutect2, varscan2
- SFI1 | c.1499G>A p.R500H (on ENST00000400288 / NM_001007467.3; = p.R469H on NM_014775.4) | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs367598903; called by muse, mutect2, varscan2
- SIGLEC10 | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 37/138 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.304); catalogued as COSV59481303; called by muse, mutect2, varscan2
- SLC19A3 | c.1472T>C p.I491T | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0.018); catalogued as COSV51452585; called by muse, mutect2, varscan2
- SLC1A7 | c.1291G>A p.V431I | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.869); catalogued as COSV57013258; called by muse, mutect2, varscan2
- SLC23A3 | c.248C>T p.P83L | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.881); catalogued as COSV55406990; called by muse, mutect2
- SLC25A10 | c.353C>T p.T118M | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1267876821, COSV58970363; called by muse, mutect2, varscan2
- SLC25A23 | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.662); catalogued as rs939062045, COSV51191253; called by muse, mutect2, varscan2
- SLC2A5 | c.1082C>A p.A361E | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as COSV66236464; called by muse, mutect2, varscan2
- SLC35B2 | c.1002_1003del p.H334Qfs*2 | Frame Shift Del (DEL) | VAF 14/58 reads (24%) | catalogued as rs1561907670; called by pindel, varscan2
- SLC35G5 | c.268C>T p.R90C | Missense Mutation (SNP) | VAF 53/192 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs377667979; called by muse, mutect2, varscan2
- SLC41A3 | c.1243G>T p.G415C | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as COSV59987920; called by muse, mutect2, varscan2
- SLC6A1 | c.953G>T p.R318M | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV55115036; called by muse, mutect2, varscan2
- SLITRK4 | c.218T>C p.I73T | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as COSV62023581; called by muse, mutect2, varscan2
- SMAD3 | c.883C>T p.R295W | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1399970718, COSV59281513; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMG6 | c.3520C>T p.R1174* | Nonsense Mutation (SNP) | VAF 35/163 reads (21%) | catalogued as COSV53966700; called by muse, mutect2, varscan2
- SMG7 | c.2545del p.M849* | Frame Shift Del (DEL) | VAF 33/120 reads (28%) | catalogued as rs749889899; called by mutect2, varscan2
- SOAT1 | c.794T>C p.M265T | Missense Mutation (SNP) | VAF 10/244 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62654001; called by muse, mutect2
- SOAT1 | c.925C>G p.R309G | Missense Mutation (SNP) | VAF 61/250 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62654008; called by muse, mutect2, varscan2
- SPECC1 | c.908del p.N303Tfs*63 | Frame Shift Del (DEL) | VAF 6/42 reads (14%) | catalogued as COSV54965656; called by mutect2, varscan2
- SPTBN2 | c.2814C>T p.H938= | Splice Region (SNP) | VAF 52/171 reads (30%) | catalogued as COSV59451522; called by muse, mutect2, varscan2
- SPTBN5 | c.4826C>T p.A1609V | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.105); catalogued as COSV58020188; called by muse, mutect2, varscan2
- SREBF1 | c.3331A>G p.M1111V | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV55392586; called by muse, mutect2, varscan2
- SREK1IP1 | c.381del p.K129Nfs*29 | Frame Shift Del (DEL) | VAF 25/87 reads (29%) | catalogued as rs1470980144, COSV72486131; called by mutect2, pindel, varscan2
- ST7 | c.784C>T p.Q262* (on ENST00000265437 / NM_021908.3; = p.Q239* on NM_018412.4) | Nonsense Mutation (SNP) | VAF 10/46 reads (22%) | catalogued as COSV55384241; called by muse, mutect2, varscan2
- STAG2 | c.2345C>T p.T782I | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.028); catalogued as COSV54357620; called by muse, mutect2, varscan2
- STAG2 | c.2840G>C p.G947A | Missense Mutation (SNP) | VAF 60/211 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.012); catalogued as COSV54357629; called by muse, mutect2, varscan2
- STEAP4 | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs924562362, COSV57329235; called by muse, mutect2, varscan2
- STOML2 | c.272C>T p.A91V | Missense Mutation (SNP) | VAF 10/133 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV59716084; called by muse, mutect2
- SULT1B1 | c.575del p.L192Cfs*6 | Frame Shift Del (DEL) | VAF 66/283 reads (23%) | catalogued as rs1316574540; called by mutect2, pindel, varscan2
- SYNE1 | c.18985C>T p.P6329S (on ENST00000367255 / NM_182961.4; = p.P6258S on NM_033071.3) | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.164); catalogued as COSV54972330; called by muse, mutect2, varscan2
- TAB3 | c.890C>A p.P297H | Missense Mutation (SNP) | VAF 40/172 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); catalogued as COSV55836690; called by muse, mutect2, varscan2
- TAF1 | c.610C>T p.P204S (on ENST00000373790 / NM_138923.4; = p.P225S on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.091); catalogued as COSV52112521; called by muse, mutect2, varscan2
- TAZ | c.629T>C p.L210P | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM994451, COSV54796392; called by muse, mutect2, varscan2
- TBC1D14 | c.1042C>T p.R348* | Nonsense Mutation (SNP) | VAF 52/235 reads (22%) | catalogued as COSV63391604; called by muse, mutect2, varscan2
- TBC1D31 | c.604dup p.C202Lfs*10 | Frame Shift Ins (INS) | VAF 51/229 reads (22%) | catalogued as rs1327142910; called by mutect2, pindel, varscan2
- TBX4 | c.1112del p.P371Lfs*8 | Frame Shift Del (DEL) | VAF 8/42 reads (19%) | catalogued as rs754897911; ClinVar: uncertain significance; called by mutect2, varscan2
- TCF7L2 | c.1454del p.K485Sfs*23 (on ENST00000355995 / NM_001367943.1; = p.K462Sfs*23 on NM_030756.5) | Frame Shift Del (DEL) | VAF 10/17 reads (59%) | catalogued as rs745872748; called by mutect2, varscan2
- TET2 | c.2546C>T p.T849I | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs773893492, COSV54409631; called by muse, mutect2, varscan2
- TEX13B | c.428G>T p.R143L | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV57202718; called by muse, mutect2, varscan2
- TGFBRAP1 | c.1032A>T p.K344N | Missense Mutation (SNP) | VAF 43/152 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.199); catalogued as COSV51511886; called by muse, mutect2, varscan2
- TGM5 | c.107del p.G36Afs*67 (on ENST00000220420 / NM_201631.4; = p.G36Afs*45 on NM_004245.4) | Frame Shift Del (DEL) | VAF 13/68 reads (19%) | catalogued as COSV55012031; called by mutect2, pindel, varscan2
- THBS4 | c.2609C>T p.S870F | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1324311104, COSV63469201; called by muse, mutect2, varscan2
- TMC2 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs1401863411, COSV62652385; called by muse, mutect2, varscan2
- TMED6 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 77/244 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs138022310; called by muse, mutect2, varscan2
- TMEM171 | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV55129273; called by muse, mutect2, varscan2
- TMEM200A | c.341G>A p.R114H | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs1416618515, COSV51648874; called by muse, mutect2, varscan2
- TMEM67 | c.805G>T p.G269* | Nonsense Mutation (SNP) | VAF 80/258 reads (31%) | catalogued as COSV60039003; called by muse, mutect2, varscan2
- TMTC3 | c.2274del p.K758Nfs*31 | Frame Shift Del (DEL) | VAF 12/41 reads (29%) | catalogued as rs1304750530; called by mutect2, pindel, varscan2
- TRAJ23 | c.44C>T p.T15M | Missense Mutation (SNP) | VAF 54/151 reads (36%) | PolyPhen probably damaging (0.999); catalogued as rs371372463; called by muse, mutect2, varscan2
- TRAPPC6A | c.179G>T p.R60M (on ENST00000585934 / NM_001270891.2; = p.R74M on NM_024108.3) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV50065172; called by mutect2, varscan2
- TRDN | c.1186del p.K396Nfs*27 | Frame Shift Del (DEL) | VAF 56/188 reads (30%) | catalogued as rs748084011, COSV62112443; called by mutect2, pindel, varscan2
- TRIM37 | c.1801A>G p.T601A | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT tolerated, low confidence (0.99); PolyPhen benign (0); catalogued as COSV51883534; called by muse, mutect2, varscan2
- TRIO | c.2366G>A p.R789H | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV60083068; called by muse, mutect2, varscan2
- TRPM5 | c.1972G>A p.A658T | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.483); catalogued as rs746934553, COSV50144429; called by muse, mutect2, varscan2
- TSPAN7 | c.516dup p.S173Qfs*8 | Frame Shift Ins (INS) | VAF 10/44 reads (23%) | catalogued as rs752121179; called by mutect2, varscan2
- TTC26 | c.1243-2A>G p.X415_splice | Splice Site (SNP) | VAF 95/375 reads (25%) | catalogued as COSV58271127; called by muse, mutect2, varscan2
- TTN | c.77102C>G p.T25701S (on ENST00000591111; = p.T18277S on NM_003319.4) | Missense Mutation (SNP) | VAF 8/37 reads (22%) | PolyPhen benign (0); catalogued as COSV60033411, COSV60081813, COSV60154931; called by muse, mutect2, varscan2
- TULP2 | c.784C>T p.R262C | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as rs139664178; called by muse, mutect2, varscan2
- TYW3 | c.602T>C p.M201T | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV63802788; called by muse, mutect2, varscan2
- UBR4 | c.4180C>T p.R1394C | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.982); catalogued as rs758929243, COSV64388882; called by muse, varscan2
- UBXN2A | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.928); catalogued as COSV58336328; called by muse, mutect2, varscan2
- UCKL1 | c.1344C>A p.H448Q | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as COSV62402768, COSV62403362; called by muse, mutect2, varscan2
- UPP2 | c.14T>C p.I5T | Missense Mutation (SNP) | VAF 65/196 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.013); catalogued as COSV50046897; called by muse, mutect2, varscan2
- URB2 | c.1132G>A p.D378N | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765588103, COSV50987601; called by muse, mutect2, varscan2
- USH2A | c.10442G>A p.S3481N | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as COSV56364521; called by muse, mutect2, varscan2
- USP11 | c.787G>A p.D263N (on ENST00000218348; = p.D220N on NM_001371072.1) | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV54473155; called by muse, mutect2, varscan2
- USP16 | c.826G>A p.V276M | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57625232; called by muse, mutect2, varscan2
- USP26 | c.1836dup p.G613Rfs*6 | Frame Shift Ins (INS) | VAF 22/81 reads (27%) | catalogued as rs749830910; called by mutect2, varscan2
- USP48 | c.893G>A p.R298H | Missense Mutation (SNP) | VAF 48/165 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as rs771915031, COSV57609578; called by muse, mutect2, varscan2
- VEGFB | c.386del p.K129Rfs*5 | Frame Shift Del (DEL) | VAF 18/128 reads (14%) | catalogued as rs747177567, COSV100374813; called by mutect2, varscan2
- VSIG1 | c.664del p.C222Afs*19 | Frame Shift Del (DEL) | VAF 33/151 reads (22%) | catalogued as COSV54259096; called by mutect2, pindel, varscan2
- WASHC2C | c.502C>T p.R168W | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1393940516, COSV60491243; called by mutect2, varscan2
- WDTC1 | c.868del p.E290Nfs*8 | Frame Shift Del (DEL) | VAF 12/49 reads (24%) | catalogued as rs747972901, COSV60089251; called by mutect2, varscan2
- ZBTB21 | c.1217G>A p.R406H | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.615); catalogued as rs534651803, COSV60403902; called by muse, mutect2, varscan2
- ZBTB7B | c.83G>A p.R28H (on ENST00000292176; = p.R62H on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52692415; called by muse, mutect2, varscan2
- ZBTB7C | c.394del p.D132Tfs*90 | Frame Shift Del (DEL) | VAF 47/190 reads (25%) | catalogued as COSV59691020; called by mutect2, pindel, varscan2
- ZFHX3 | c.10630C>G p.L3544V | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as rs757184727, COSV51717350; called by muse, mutect2, varscan2
- ZIC4 | c.449C>T p.T150I | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101268096, COSV67171581; called by muse, mutect2, varscan2
- ZMYM4 | c.806T>C p.L269P | Missense Mutation (SNP) | VAF 47/179 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.022); catalogued as COSV58910039; called by muse, mutect2, varscan2
- ZMYND15 | c.1763G>A p.R588H (on ENST00000433935 / NM_001136046.3; = p.R549H on NM_032265.2) | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs369450548, COSV99351184; called by muse, mutect2, varscan2
- ZNF134 | c.1165C>T p.R389* | Nonsense Mutation (SNP) | VAF 24/102 reads (24%) | catalogued as rs368407520, COSV68696317; called by muse, mutect2, varscan2
- ZNF175 | c.362T>C p.M121T | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0.012); catalogued as COSV51795393; called by muse, mutect2, varscan2
- ZNF211 | c.1603del p.R535Gfs*89 (on ENST00000347302 / NM_198855.4; = p.R548Gfs*89 on NM_006385.5) | Frame Shift Del (DEL) | VAF 40/145 reads (28%) | catalogued as rs1182033175, COSV53743356; called by mutect2, pindel, varscan2
- ZNF292 | c.6145del p.S2049Vfs*11 | Frame Shift Del (DEL) | VAF 16/49 reads (33%) | catalogued as rs764995318; called by mutect2, varscan2
- ZNF365 | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as COSV67925425; called by muse, mutect2, varscan2
- ZNF48 | c.745del p.R249Dfs*43 | Frame Shift Del (DEL) | VAF 5/48 reads (10%) | catalogued as rs780189754; called by mutect2, pindel, varscan2
- ZNF511 | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.077); catalogued as rs776627133, COSV62920045; called by muse, mutect2, varscan2
- ZNF667 | c.602A>G p.E201G | Missense Mutation (SNP) | VAF 53/237 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV52634078; called by muse, mutect2, varscan2
- ZNF74 | c.914_916del p.F305del | In Frame Del (DEL) | VAF 7/27 reads (26%) | catalogued as rs781277318; called by pindel, varscan2
- ZNF778 | c.760G>A p.V254I | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs533457711, COSV60601322, COSV60602582; called by muse, mutect2, varscan2
- ZNF808 | c.2156G>T p.R719M | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.224); catalogued as COSV63119715; called by muse, mutect2, varscan2
- ADAMTS9 | c.866del p.L289Yfs*7 | Frame Shift Del (DEL) | VAF 46/209 reads (22%) | called by mutect2, pindel, varscan2
- ADGRA3 | c.3689_3690dup p.Q1231Dfs*37 | Frame Shift Ins (INS) | VAF 12/62 reads (19%) | called by mutect2, varscan2
- AGO1 | c.49del p.L17Cfs*99 | Frame Shift Del (DEL) | VAF 19/47 reads (40%) | called by mutect2, pindel, varscan2
- AKAP10 | c.166dup p.S56Kfs*3 | Frame Shift Ins (INS) | VAF 43/152 reads (28%) | called by mutect2, pindel, varscan2
- AKR1B15 | c.814del p.T272Pfs*6 | Frame Shift Del (DEL) | VAF 11/68 reads (16%) | called by mutect2, pindel, varscan2
- AMMECR1L | c.547del p.L183* | Frame Shift Del (DEL) | VAF 19/87 reads (22%) | called by mutect2, pindel, varscan2
- ARID4B | c.2656dup p.R886Kfs*22 | Frame Shift Ins (INS) | VAF 39/195 reads (20%) | called by mutect2, pindel, varscan2
- ASB4 | c.1119_1120del p.F374Yfs*5 | Frame Shift Del (DEL) | VAF 27/150 reads (18%) | called by pindel, varscan2
- BEST3 | c.45dup p.G16Wfs*4 | Frame Shift Ins (INS) | VAF 26/105 reads (25%) | called by mutect2, varscan2
- BRF1 | c.939del p.K313Nfs*20 | Frame Shift Del (DEL) | VAF 93/318 reads (29%) | called by mutect2, pindel, varscan2
- CCDC88B | c.1901dup p.L634Ffs*4 | Frame Shift Ins (INS) | VAF 4/28 reads (14%) | called by mutect2, varscan2
- CEP95 | c.1872_1874del p.L625del | In Frame Del (DEL) | VAF 24/113 reads (21%) | called by pindel, varscan2
- CHD3 | c.4954del p.E1652Rfs*27 (on ENST00000330494 / NM_001005273.3; = p.E1711Rfs*27 on NM_001005271.3) | Frame Shift Del (DEL) | VAF 30/123 reads (24%) | called by mutect2, pindel, varscan2
- COL12A1 | c.4083dup p.E1362* | Frame Shift Ins (INS) | VAF 12/66 reads (18%) | called by mutect2, pindel, varscan2
- COL24A1 | c.423del p.K141Nfs*2 | Frame Shift Del (DEL) | VAF 11/41 reads (27%) | called by mutect2, pindel, varscan2
- COL9A3 | c.846+3_846+6del p.X282_splice | Splice Site (DEL) | VAF 14/56 reads (25%) | called by mutect2, pindel, varscan2
- CPEB2 | c.2941del p.C981Vfs*31 | Frame Shift Del (DEL) | VAF 30/116 reads (26%) | called by mutect2, pindel, varscan2
- DAGLB | c.1805_1807del p.E602del | In Frame Del (DEL) | VAF 8/38 reads (21%) | called by pindel, varscan2
- DUS3L | c.1908del p.S637Afs*30 | Frame Shift Del (DEL) | VAF 5/21 reads (24%) | called by mutect2, pindel, varscan2
- ENPEP | c.1422del p.F474Lfs*13 | Frame Shift Del (DEL) | VAF 39/186 reads (21%) | called by mutect2, pindel, varscan2
- F12 | c.191dup p.R66Pfs*15 | Frame Shift Ins (INS) | VAF 23/77 reads (30%) | called by mutect2, pindel, varscan2
- FMNL2 | c.1412del p.K471Rfs*5 | Frame Shift Del (DEL) | VAF 30/103 reads (29%) | called by mutect2, pindel, varscan2
- FOXP3 | c.616_618del p.K206del | In Frame Del (DEL) | VAF 11/36 reads (31%) | called by mutect2, pindel, varscan2
- FUT11 | c.1384del p.E462Kfs*6 | Frame Shift Del (DEL) | VAF 33/134 reads (25%) | called by mutect2, pindel, varscan2
- GABRB2 | c.177del p.V60Wfs*5 | Frame Shift Del (DEL) | VAF 9/73 reads (12%) | called by mutect2, pindel
- GALC | c.1503del p.F501Lfs*52 | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | called by mutect2, pindel, varscan2
- GALK1 | c.364del p.L122Sfs*42 | Frame Shift Del (DEL) | VAF 8/29 reads (28%) | called by mutect2, pindel, varscan2
- HIP1R | c.985del p.E329Sfs*20 | Frame Shift Del (DEL) | VAF 7/21 reads (33%) | called by mutect2, varscan2
- INPP4A | c.224del p.P75Lfs*24 | Frame Shift Del (DEL) | VAF 16/68 reads (24%) | called by mutect2, pindel, varscan2
- INTS6L | c.2259del p.D754Tfs*3 | Frame Shift Del (DEL) | VAF 26/90 reads (29%) | called by mutect2, pindel, varscan2
- JAK1 | c.2580del p.K860Nfs*16 | Frame Shift Del (DEL) | VAF 36/149 reads (24%) | called by mutect2, varscan2
- KCNA4 | c.663dup p.D222* | Frame Shift Ins (INS) | VAF 20/82 reads (24%) | called by mutect2, varscan2
- KLF3 | c.589dup p.I197Nfs*2 | Frame Shift Ins (INS) | VAF 38/128 reads (30%) | called by mutect2, varscan2
- LIN9 | c.756del p.F252Lfs*8 (on ENST00000366808 / NM_001270410.2; = p.F197Lfs*8 on NM_173083.3 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 98/437 reads (22%) | called by mutect2, pindel, varscan2
- MBD6 | c.2012del p.P671Lfs*4 | Frame Shift Del (DEL) | VAF 10/52 reads (19%) | called by mutect2, pindel
- MED4 | c.294del p.E99Kfs*2 | Frame Shift Del (DEL) | VAF 124/550 reads (23%) | called by mutect2, pindel, varscan2
- MFSD14B | c.284del p.L95* | Frame Shift Del (DEL) | VAF 57/261 reads (22%) | called by mutect2, pindel, varscan2
- MROH1 | c.1486C>T p.R496C | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- MTBP | c.86_118del p.V29_P39del | In Frame Del (DEL) | VAF 5/54 reads (9%) | called by mutect2, pindel, varscan2
- MUSK | c.2326del p.Y776Ifs*92 | Frame Shift Del (DEL) | VAF 17/63 reads (27%) | called by mutect2, pindel, varscan2
- NGRN | c.79del p.V27Wfs*31 | Frame Shift Del (DEL) | VAF 9/30 reads (30%) | called by mutect2, pindel, varscan2
- NOC3L | c.2303del p.L768* | Frame Shift Del (DEL) | VAF 21/84 reads (25%) | called by mutect2, pindel, varscan2
- NSRP1 | c.406del p.E136Sfs*9 | Frame Shift Del (DEL) | VAF 38/184 reads (21%) | called by mutect2, pindel, varscan2
- PCGF2 | c.451del p.L151Wfs*22 | Frame Shift Del (DEL) | VAF 20/112 reads (18%) | called by mutect2, pindel, varscan2
- PCLO | c.14543dup p.P4849Afs*14 | Frame Shift Ins (INS) | VAF 44/184 reads (24%) | called by mutect2, pindel, varscan2
- PDZD2 | c.6719del p.P2240Hfs*14 | Frame Shift Del (DEL) | VAF 10/39 reads (26%) | called by mutect2, pindel, varscan2
- PIK3R1 | c.1898_1899del p.K633Sfs*2 (on ENST00000521381 / NM_181523.3; = p.K363Sfs*2 on NM_181504.4) | Frame Shift Del (DEL) | VAF 26/119 reads (22%) | called by mutect2, pindel, varscan2
- PRSS36 | c.2120del p.P707Rfs*26 | Frame Shift Del (DEL) | VAF 5/28 reads (18%) | called by mutect2, pindel, varscan2
- RANBP2 | c.9602del p.K3201Rfs*16 | Frame Shift Del (DEL) | VAF 72/329 reads (22%) | called by mutect2, pindel, varscan2
- RNF168 | c.1284del p.K428Nfs*2 | Frame Shift Del (DEL) | VAF 70/320 reads (22%) | called by mutect2, pindel, varscan2
- RO60 | c.1494_1497del p.C499Efs*2 | Frame Shift Del (DEL) | VAF 38/148 reads (26%) | called by pindel, varscan2
- SCAF4 | c.2798del p.G933Vfs*151 | Frame Shift Del (DEL) | VAF 24/72 reads (33%) | called by mutect2, pindel, varscan2
- SCN3A | c.4473dup p.Y1492Ifs*30 | Frame Shift Ins (INS) | VAF 45/228 reads (20%) | called by mutect2, pindel, varscan2
- SCP2 | c.532del p.I178Lfs*29 | Frame Shift Del (DEL) | VAF 43/215 reads (20%) | called by mutect2, pindel, varscan2
- SKIV2L | c.1504del p.E502Sfs*28 | Frame Shift Del (DEL) | VAF 11/61 reads (18%) | called by mutect2, pindel, varscan2
- SLC22A23 | c.932dup p.G312Wfs*66 | Frame Shift Ins (INS) | VAF 6/31 reads (19%) | called by mutect2, pindel, varscan2
- SPATA31A3 | c.586C>T p.P196S | Missense Mutation (SNP) | VAF 40/132 reads (30%) | SIFT tolerated (0.63); PolyPhen benign (0.047); called by mutect2, varscan2
- STRN3 | c.715dup p.R239Kfs*5 | Frame Shift Ins (INS) | VAF 52/221 reads (24%) | called by mutect2, pindel, varscan2
- SYNPO2L | c.1704dup p.A569Rfs*4 (on ENST00000394810 / NM_001114133.3; = p.A345Rfs*4 on NM_024875.5) | Frame Shift Ins (INS) | VAF 4/10 reads (40%) | called by mutect2, varscan2
- TCERG1 | c.2539dup p.I847Nfs*14 | Frame Shift Ins (INS) | VAF 35/160 reads (22%) | called by mutect2, pindel, varscan2
- TEK | c.2938del p.I980* | Frame Shift Del (DEL) | VAF 41/207 reads (20%) | called by mutect2, pindel, varscan2
- TGM1 | c.927dup p.M310Dfs*25 | Frame Shift Ins (INS) | VAF 7/22 reads (32%) | called by mutect2, pindel, varscan2
- TIAL1 | c.128_129del p.E43Afs*5 | Frame Shift Del (DEL) | VAF 15/132 reads (11%) | called by pindel, varscan2
- TMEM200A | c.192del p.I66Ffs*2 | Frame Shift Del (DEL) | VAF 47/228 reads (21%) | called by mutect2, pindel, varscan2
- TMEM200C | c.365del p.G122Vfs*140 | Frame Shift Del (DEL) | VAF 6/34 reads (18%) | called by mutect2, pindel, varscan2
- TRIM9 | c.142del p.Q48Rfs*21 | Frame Shift Del (DEL) | VAF 6/18 reads (33%) | called by mutect2, pindel, varscan2
- TRIP12 | c.3583del p.S1195Lfs*24 | Frame Shift Del (DEL) | VAF 44/223 reads (20%) | called by mutect2, pindel, varscan2
- USP12 | c.750del p.K250Nfs*4 | Frame Shift Del (DEL) | VAF 39/176 reads (22%) | called by mutect2, pindel, varscan2
- YY2 | c.669dup p.L224Vfs*5 | Frame Shift Ins (INS) | VAF 9/86 reads (10%) | called by mutect2, pindel, varscan2
- ZNF536 | c.3526del p.E1176Rfs*14 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | called by mutect2, pindel
- ZNF75D | c.972_973del p.H324Qfs*21 | Frame Shift Del (DEL) | VAF 68/271 reads (25%) | called by pindel, varscan2
- ACTR1A | c.825C>T p.I275= | Silent (SNP) | VAF 22/105 reads (21%) | catalogued as COSV64023275; called by muse, mutect2, varscan2
- ADAM8 | c.1347G>A p.A449= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as rs373848180, COSV69864605; called by muse, mutect2, varscan2
- ADAMTS17 | c.1341C>T p.C447= | Silent (SNP) | VAF 4/41 reads (10%) | catalogued as rs750831099, COSV99172268; called by mutect2, varscan2
- ANK1 | c.5178G>A p.T1726= | Silent (SNP) | VAF 27/88 reads (31%) | catalogued as rs756122138, COSV55880551; called by muse, mutect2, varscan2
- ARHGAP19 | c.1266C>A p.S422= | Silent (SNP) | VAF 25/92 reads (27%) | catalogued as COSV57392660; called by muse, mutect2, varscan2
- ARHGEF5 | c.1299C>T p.P433= | Silent (SNP) | VAF 23/75 reads (31%) | catalogued as rs775212336, COSV50209971, COSV99282716; called by muse, mutect2, varscan2
- ARL10 | c.597G>A p.Q199= | Silent (SNP) | VAF 33/90 reads (37%) | catalogued as COSV59990591; called by muse, mutect2, varscan2
- BBC3 | c.639T>C p.P213= (on ENST00000449228 / NM_001127240.3; = p.L179P on NM_014417.5) | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV56262620; called by muse, mutect2, varscan2
- BIRC6 | c.5283T>C p.L1761= | Silent (SNP) | VAF 78/381 reads (20%) | catalogued as rs1159863260, COSV70198822; called by muse, varscan2
- C18orf54 | c.480T>C p.G160= | Silent (SNP) | VAF 27/110 reads (25%) | catalogued as COSV55617982; called by muse, mutect2, varscan2
- C1QL1 | c.627G>A p.A209= | Silent (SNP) | VAF 37/126 reads (29%) | catalogued as COSV53647067, COSV99492818; called by muse, mutect2, varscan2
- CAMTA2 | c.2154T>G p.A718= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV61834687; called by muse, mutect2
- CCDC170 | c.1590C>T p.N530= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as rs375623063; called by muse, mutect2, varscan2
- CDH24 | c.1729C>T p.L577= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV57460835; called by muse, mutect2, varscan2
- CDH3 | c.1116C>T p.D372= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as rs139565232; called by muse, mutect2, varscan2
- CENPF | c.3867T>C p.L1289= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as COSV65274752; called by muse, mutect2, varscan2
- CHFR | c.765C>T p.P255= (on ENST00000432561 / NM_001161345.1; = p.P214= on NM_018223.2) | Silent (SNP) | VAF 110/376 reads (29%) | catalogued as rs1025589682, COSV57174107; called by muse, mutect2, varscan2
- CHRNB3 | c.648C>T p.G216= | Silent (SNP) | VAF 15/74 reads (20%) | catalogued as rs775527839, COSV51494837; called by muse, mutect2, varscan2
- CLEC4E | c.438C>T p.V146= | Silent (SNP) | VAF 42/141 reads (30%) | catalogued as rs775903909, COSV55225743; called by muse, mutect2, varscan2
- COL12A1 | c.8223T>C p.C2741= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as COSV59395342; called by muse, mutect2, varscan2
- COP1 | c.1056G>A p.T352= | Silent (SNP) | VAF 44/146 reads (30%) | catalogued as rs369471153; called by muse, mutect2, varscan2
- CTTN | c.1521C>T p.G507= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as rs1414999274, COSV57232098; called by muse, mutect2, varscan2
- CYP2R1 | c.736C>T p.L246= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as COSV58127483; called by muse, mutect2, varscan2
- DCLK3 | c.1107C>T p.V369= | Silent (SNP) | VAF 29/97 reads (30%) | catalogued as rs373705108; called by muse, mutect2, varscan2
- DGAT2L6 | c.996A>G p.Q332= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as COSV60717650; called by muse, mutect2, varscan2
- DNAH10 | c.5565C>T p.Y1855= (on ENST00000409039; = p.Y1794= on NM_207437.3) | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as rs543140648, COSV68992985; called by muse, mutect2, varscan2
- DNAH10 | c.7683T>C p.N2561= (on ENST00000409039; = p.N2500= on NM_207437.3) | Silent (SNP) | VAF 24/109 reads (22%) | catalogued as rs755053000, COSV68992992; called by muse, mutect2, varscan2
- DOC2A | c.660G>A p.A220= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as rs765364473, COSV58751337; called by muse, varscan2
- FAM181A | c.421C>T p.L141= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV50888392; called by muse, mutect2, varscan2
- FAT2 | c.9264G>A p.T3088= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as rs772946190, COSV55819046; called by muse, mutect2
- FBXW10 | c.1155C>T p.N385= | Silent (SNP) | VAF 63/245 reads (26%) | catalogued as rs200851525, COSV57316911; called by muse, mutect2, varscan2
- GALT | c.1101C>T p.H367= | Silent (SNP) | VAF 14/93 reads (15%) | catalogued as COSV58840576; called by muse, mutect2, varscan2
- GDF9 | c.1122G>A p.P374= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as rs775109233, COSV51526024; called by muse, mutect2, varscan2
- GIT2 | c.903G>A p.T301= (on ENST00000355312 / NM_057169.5; = p.T303= on NM_014776.5) | Silent (SNP) | VAF 21/60 reads (35%) | catalogued as rs780484968, COSV58080618; called by muse, mutect2, varscan2
- GRIN1 | c.2790G>A p.Q930= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as COSV59295216; called by muse, mutect2
- GTF3C5 | c.417C>T p.G139= | Silent (SNP) | VAF 17/39 reads (44%) | catalogued as rs140767076; called by muse, mutect2, varscan2
- GYS2 | c.1692C>T p.C564= | Silent (SNP) | VAF 29/102 reads (28%) | catalogued as COSV53922909; called by muse, varscan2
- HCN2 | c.658C>T p.L220= | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as COSV52114437; called by muse, mutect2, varscan2
- HECTD3 | c.1776C>T p.C592= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as COSV64670127; called by muse, mutect2, varscan2
- HEG1 | c.2001C>T p.S667= | Silent (SNP) | VAF 45/155 reads (29%) | catalogued as COSV60761489; called by muse, mutect2, varscan2
- HERC2 | c.2622C>T p.S874= | Silent (SNP) | VAF 4/16 reads (25%) | called by muse, mutect2
- HIVEP1 | c.7686C>T p.A2562= | Silent (SNP) | VAF 32/151 reads (21%) | catalogued as rs372967941, COSV101045438; called by muse, mutect2, varscan2
- HTR1A | c.456C>T p.R152= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV60500672; called by muse, mutect2, varscan2
- IDS | c.63C>T p.C21= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as COSV61712287, COSV61712661; called by muse, mutect2, varscan2
- IFT122 | c.2778C>G p.L926= (on ENST00000348417 / NM_052989.3; = p.L867= on NM_018262.4) | Silent (SNP) | VAF 9/133 reads (7%) | catalogued as COSV56202720; called by muse, mutect2
- IPMK | c.99G>A p.P33= | Silent (SNP) | VAF 3/11 reads (27%) | catalogued as rs749061891, COSV61703435; called by muse, mutect2, varscan2
- IRS4 | c.3702C>T p.D1234= | Silent (SNP) | VAF 31/110 reads (28%) | catalogued as COSV64533288; called by muse, mutect2, varscan2
- IRX2 | c.372C>T p.D124= | Silent (SNP) | VAF 37/135 reads (27%) | catalogued as rs1014895683, COSV100121589, COSV57409988; called by muse, mutect2, varscan2
- KANSL1L | c.2208C>T p.S736= | Silent (SNP) | VAF 54/229 reads (24%) | catalogued as COSV55991919; called by muse, mutect2, varscan2
- KCNS3 | c.1146G>A p.A382= | Silent (SNP) | VAF 30/94 reads (32%) | catalogued as rs773202985, COSV58406647; called by muse, mutect2, varscan2
- KIF13B | c.5169C>T p.A1723= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as rs1393010827, COSV68094228; called by muse, mutect2, varscan2
- KRT5 | c.1350G>A p.L450= | Silent (SNP) | VAF 29/77 reads (38%) | catalogued as COSV52860520; called by muse, mutect2, varscan2
- LZTR1 | c.972C>T p.V324= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as COSV53147239; called by muse, mutect2, varscan2
- MICB | c.1146C>T p.G382= | Silent (SNP) | VAF 25/79 reads (32%) | catalogued as rs541452071, COSV52855977; called by muse, mutect2, varscan2
- MKI67 | c.1953G>A p.S651= | Silent (SNP) | VAF 22/95 reads (23%) | catalogued as rs142241283; called by muse, mutect2, varscan2
- MKS1 | c.1299G>A p.T433= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as rs749503564, COSV56596280; called by muse, mutect2
- MRPS28 | c.513A>T p.G171= | Silent (SNP) | VAF 50/165 reads (30%) | catalogued as COSV52562474; called by muse, mutect2, varscan2
- MTMR3 | c.1806T>C p.D602= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV60304016; called by muse, mutect2, varscan2
- MTUS2 | c.2013G>A p.P671= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as rs1424838911, COSV70916627; called by muse, mutect2, varscan2
- MYO6 | c.1254T>C p.N418= | Silent (SNP) | VAF 74/196 reads (38%) | catalogued as COSV64118834; called by muse, mutect2, varscan2
- NDFIP2 | c.552T>C p.P184= | Silent (SNP) | VAF 17/74 reads (23%) | catalogued as COSV54527908; called by muse, mutect2, varscan2
- NLE1 | c.1239C>T p.H413= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs369573413; called by mutect2, varscan2
- NOL12 | c.279G>A p.T93= | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as rs753142556, COSV63031055; called by muse, mutect2, varscan2
- OCA2 | c.2463C>T p.C821= | Silent (SNP) | VAF 45/159 reads (28%) | catalogued as COSV62344775; called by muse, mutect2, varscan2
- OR10AG1 | c.510T>C p.C170= | Silent (SNP) | VAF 23/107 reads (21%) | catalogued as COSV56632761; called by muse, mutect2, varscan2
- OR4D9 | c.330A>C p.A110= | Silent (SNP) | VAF 11/122 reads (9%) | catalogued as COSV61434577; called by muse, mutect2
- OR8B2 | c.534G>A p.L178= | Silent (SNP) | VAF 20/53 reads (38%) | catalogued as COSV66664601; called by muse, mutect2, varscan2
- P2RY4 | c.639C>T p.C213= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as COSV65736617; called by muse, mutect2, varscan2
- PANK4 | c.1431G>A p.A477= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as rs755165110, COSV65866639; called by muse, mutect2, varscan2
- PC | c.3078C>T p.T1026= | Silent (SNP) | VAF 21/67 reads (31%) | catalogued as rs750411329, COSV58992614; called by muse, mutect2, varscan2
- PCDHB6 | c.1431C>T p.D477= | Silent (SNP) | VAF 25/95 reads (26%) | catalogued as COSV50696295; called by muse, mutect2, varscan2
- PCDHGB4 | c.1719C>T p.F573= | Silent (SNP) | VAF 3/18 reads (17%) | catalogued as rs1166074538, COSV53941626; called by muse, mutect2
- PCDHGB5 | c.1944G>A p.P648= | Silent (SNP) | VAF 18/64 reads (28%) | catalogued as COSV53941638; called by muse, mutect2, varscan2
- PDS5A | c.2211A>G p.K737= | Silent (SNP) | VAF 11/238 reads (5%) | catalogued as COSV57825446; called by muse, mutect2
- PEX19 | c.162G>A p.S54= | Silent (SNP) | VAF 25/116 reads (22%) | catalogued as rs540593146, COSV63619435; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PGAM4 | c.36C>T p.G12= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as rs201946447, COSV100431680, COSV58445835; called by muse, mutect2, varscan2
- PHRF1 | c.183G>A p.A61= | Silent (SNP) | VAF 27/108 reads (25%) | catalogued as rs539003415, COSV52755222; called by muse, mutect2, varscan2
- PIGR | c.12C>T p.F4= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as rs867475005, COSV62903880; called by muse, mutect2
- PLK3 | c.1761C>T p.Y587= | Silent (SNP) | VAF 32/93 reads (34%) | catalogued as rs777784782, COSV59499032; called by muse, mutect2, varscan2
- POLQ | c.3186G>A p.A1062= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as rs751377736, COSV51746011; called by muse, mutect2, varscan2
- PPFIA1 | c.42C>T p.G14= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as COSV54134198; called by muse, mutect2, varscan2
- PRKDC | c.831G>A p.L277= | Silent (SNP) | VAF 32/132 reads (24%) | catalogued as COSV58051163; called by muse, mutect2, varscan2
- PTPN6 | c.1164C>T p.T388= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as rs374040175; called by muse, mutect2, varscan2
- PYGM | c.402C>T p.N134= | Silent (SNP) | VAF 23/59 reads (39%) | catalogued as rs372262267, CD071383; called by muse, mutect2, varscan2
- RABL6 | c.1545C>T p.T515= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as rs765000452, COSV61035448; called by muse, mutect2, varscan2
- RALGAPA2 | c.1587T>C p.A529= | Silent (SNP) | VAF 29/130 reads (22%) | catalogued as COSV52496387; called by muse, mutect2, varscan2
- RIMBP2 | c.1101C>T p.S367= | Silent (SNP) | VAF 32/120 reads (27%) | catalogued as rs377474816, COSV99899771; called by muse, mutect2, varscan2
- RNF19A | c.546G>A p.R182= | Silent (SNP) | VAF 31/138 reads (22%) | catalogued as rs1209368340, COSV61993069; called by muse, mutect2, varscan2
- SART3 | c.1626C>A p.T542= (on ENST00000228284; = p.T524= on NM_014706.4) | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV57207105, COSV57208449; called by muse, mutect2
- SASH1 | c.3078C>T p.P1026= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as rs200262751, COSV66558885, COSV66561412; called by muse, mutect2, varscan2
- SCN3A | c.2644C>T p.L882= | Silent (SNP) | VAF 12/127 reads (9%) | catalogued as COSV51808837; called by muse, mutect2
- SCN5A | c.5226C>T p.C1742= (on ENST00000333535 / NM_198056.3; = p.C1741= on NM_000335.5) | Silent (SNP) | VAF 27/111 reads (24%) | catalogued as rs878855293, COSV61123097; ClinVar: likely benign; called by muse, mutect2, varscan2
- SCYL2 | c.1458C>T p.N486= | Silent (SNP) | VAF 99/376 reads (26%) | catalogued as rs759058211, COSV62568643; called by muse, mutect2, varscan2
- SEMA3A | c.888A>G p.P296= | Silent (SNP) | VAF 59/169 reads (35%) | catalogued as COSV54869496; called by muse, mutect2, varscan2
- SH2D3A | c.486C>T p.P162= | Silent (SNP) | VAF 31/87 reads (36%) | catalogued as rs151024410; called by muse, mutect2, varscan2
- SHROOM3 | c.5539C>T p.L1847= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as COSV56028440; called by muse, mutect2, varscan2
- SLAIN2 | c.1347T>C p.P449= | Silent (SNP) | VAF 16/73 reads (22%) | catalogued as COSV51906237; called by muse, mutect2, varscan2
- SLC2A2 | c.951C>T p.S317= | Silent (SNP) | VAF 21/86 reads (24%) | catalogued as rs1168244945, COSV58585880; called by muse, mutect2, varscan2
- SLC40A1 | c.1545A>G p.P515= | Silent (SNP) | VAF 19/81 reads (23%) | catalogued as COSV53722895; called by muse, mutect2, varscan2
- SLC7A9 | c.543C>T p.T181= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as rs149361640, COSV99195305; called by muse, mutect2, varscan2
- SPATA31E1 | c.2745C>T p.T915= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as rs750377615, COSV57790793, COSV57793525; called by muse, mutect2, varscan2
- SPDYE3 | c.1635C>T p.R545= | Silent (SNP) | VAF 33/80 reads (41%) | catalogued as rs748903725, COSV60107169; called by muse, mutect2, varscan2
- SRF | c.765C>T p.S255= | Silent (SNP) | VAF 9/159 reads (6%) | catalogued as COSV54838432; called by muse, mutect2
- ST18 | c.2358C>T p.H786= | Silent (SNP) | VAF 15/73 reads (21%) | catalogued as COSV52493094; called by muse, mutect2, varscan2
- SUPT5H | c.2835G>A p.P945= | Silent (SNP) | VAF 24/59 reads (41%) | catalogued as rs754543629, COSV63239475; called by muse, mutect2, varscan2
- SYT1 | c.666C>T p.G222= | Silent (SNP) | VAF 26/108 reads (24%) | catalogued as COSV54045709; called by muse, mutect2, varscan2
- TAF1L | c.3729G>A p.R1243= | Silent (SNP) | VAF 51/201 reads (25%) | catalogued as COSV54261498; called by muse, mutect2, varscan2
- TBCC | c.987C>A p.A329= | Silent (SNP) | VAF 10/168 reads (6%) | catalogued as COSV55130624; called by muse, mutect2
- TCEA2 | c.762G>A p.T254= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs772631450, COSV58657764; called by mutect2, varscan2
- TGM5 | c.747C>T p.G249= (on ENST00000220420 / NM_201631.4; = p.G167= on NM_004245.4) | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as rs1031364043, COSV55009943; called by muse, mutect2, varscan2
- THBS1 | c.2319C>T p.R773= | Silent (SNP) | VAF 8/110 reads (7%) | catalogued as rs1418217385, COSV52951716; called by muse, mutect2
- TMEM131 | c.5304G>A p.S1768= | Silent (SNP) | VAF 17/71 reads (24%) | catalogued as rs369661688; called by muse, mutect2, varscan2
- TOR1AIP1 | c.259C>T p.L87= | Silent (SNP) | VAF 20/52 reads (38%) | catalogued as COSV54869470; called by muse, mutect2, varscan2
- USP36 | c.2109C>T p.T703= | Silent (SNP) | VAF 32/115 reads (28%) | catalogued as rs986571602, COSV61751290; called by muse, mutect2, varscan2
- USP54 | c.4026C>T p.T1342= | Silent (SNP) | VAF 22/62 reads (35%) | catalogued as rs774313004, COSV60442190; called by muse, mutect2, varscan2
- UTRN | c.5289T>C p.T1763= | Silent (SNP) | VAF 25/83 reads (30%) | catalogued as COSV62334531; called by muse, mutect2, varscan2
- VPS16 | c.2301T>C p.H767= | Silent (SNP) | VAF 62/207 reads (30%) | catalogued as COSV66794758; called by muse, mutect2, varscan2
- VWA8 | c.4491C>T p.S1497= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as rs771260024, COSV64996046; called by muse, varscan2
- WDR86 | c.231C>T p.C77= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as rs1327994443, COSV57839787; called by muse, mutect2, varscan2
- ZFHX4 | c.4956C>T p.S1652= | Silent (SNP) | VAF 25/85 reads (29%) | catalogued as COSV50753767; called by muse, mutect2, varscan2
- ZMYM4 | c.3864C>T p.C1288= | Silent (SNP) | VAF 49/190 reads (26%) | catalogued as COSV58910051; called by muse, mutect2, varscan2
- ZNF785 | c.771G>A p.A257= | Silent (SNP) | VAF 28/84 reads (33%) | catalogued as COSV67876316; called by muse, mutect2, varscan2
- AC244258.1 | n.688T>C | RNA (SNP) | VAF 29/107 reads (27%) | called by muse, mutect2, varscan2
- COLCA2 | chr11:111296281 G>A | 5'Flank (SNP) | VAF 11/61 reads (18%) | catalogued as rs769879017; called by muse, mutect2, varscan2
- PKD1L2 | n.853G>A | RNA (SNP) | VAF 10/60 reads (17%) | catalogued as rs772490214; called by muse, mutect2, varscan2
- POLA1 | c.2947-21374G>A | Intron (SNP) | VAF 29/87 reads (33%) | catalogued as rs779221403; called by muse, mutect2, varscan2
- RMDN2 | c.452+21918del | Intron (DEL) | VAF 22/108 reads (20%) | catalogued as rs761706403; called by mutect2, varscan2
- TMEM105 | n.844del | RNA (DEL) | VAF 15/49 reads (31%) | catalogued as rs754687276, COSV100129678; called by mutect2, pindel, varscan2
- ZNF22 | chr10:45000769 del G | 5'Flank (DEL) | VAF 37/142 reads (26%) | called by mutect2, pindel, varscan2
